Somatic mutation profile of tumor specimen MMRF_2776_1_BM_CD138pos (aliquot MMRF_2776_1_BM_CD138pos_T1_KHS5U_L15725) from MMRF case MMRF_2776, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.2 years (18,708 days).
Specimen MMRF_2776_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a1a49d93-f0ea-43c0-959c-04724172571e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2776_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2776_1_PB_WBC_C3_KHS5U_L15769; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37d4fcde-0b66-441b-adbb-202a922eeb0c

The open-access MAF lists 259 somatic variants for this specimen: 82 protein-altering or splice-affecting, 43 silent, 134 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, 3'UTR 55, Silent 43, Intron 33, 5'UTR 28, 5'Flank 7, 3'Flank 6, RNA 5, Splice Site 4, Nonsense Mutation 4, Frame Shift Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A4GNT | c.650C>G p.S217* | Nonsense Mutation (SNP) | VAF 60/204 reads (29%) | catalogued as COSV52628329; called by muse, mutect2
- ACTR3C | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 77/196 reads (39%) | SIFT deleterious, low confidence (0.03); catalogued as rs1338553637; called by muse, mutect2, varscan2
- AMH | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 119/287 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as COSV55555215; called by muse, mutect2, varscan2
- CACNA1C | c.1522C>T p.R508W | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs776805699; ClinVar: uncertain significance; called by mutect2, varscan2
- CAPN12 | c.1609G>A p.D537N | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.108); catalogued as rs1363843855; called by muse, mutect2, varscan2
- CHID1 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.122); catalogued as rs962266293; called by muse, mutect2
- DUOX1 | c.2720C>T p.S907L | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as rs139045084; called by muse, mutect2, varscan2
- EZHIP | c.928T>C p.S310P | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs971642970, COSV100539703; called by muse, varscan2
- FLI1 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 61/145 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.159); catalogued as rs745372049; called by muse, mutect2, varscan2
- FUT2 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 86/170 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1229004342; called by muse, mutect2, varscan2
- FYTTD1 | c.285G>T p.K95N | Missense Mutation (SNP) | VAF 60/120 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV54085045; called by muse, mutect2, varscan2
- GOLGB1 | c.1867C>T p.P623S | Missense Mutation (SNP) | VAF 133/305 reads (44%) | SIFT tolerated (0.73); PolyPhen benign (0.372); catalogued as rs765619874, COSV61461351; called by muse, mutect2, varscan2
- GRB7 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs371861353; called by muse, mutect2, varscan2
- HDX | c.499C>A p.L167I | Missense Mutation (SNP) | VAF 62/156 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.055); catalogued as COSV52979520; called by muse, mutect2, varscan2
- IGLV3-1 | c.47-2A>C p.X16_splice | Splice Site (SNP) | VAF 79/98 reads (81%) | catalogued as rs181922188; called by muse, varscan2
- IGLV4-60 | c.81A>C p.Q27H | Missense Mutation (SNP) | VAF 99/228 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101135263; called by muse, varscan2
- IL5 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 98/260 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV51504464; called by muse, mutect2, varscan2
- INF2 | c.2616C>G p.S872R | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.28); catalogued as rs1566785104; called by muse, mutect2, varscan2
- INKA1 | c.40C>T p.R14C | Missense Mutation (SNP) | VAF 85/183 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs778961736; called by muse, mutect2, varscan2
- KIFC2 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV56759922; called by muse, mutect2, varscan2
- NIPSNAP2 | c.301C>T p.H101Y | Missense Mutation (SNP) | VAF 74/224 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as rs754262150; called by muse, mutect2, varscan2
- OPRPN | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 168/381 reads (44%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.007); catalogued as rs371348643; called by muse, mutect2, varscan2
- OR2L5 | c.413G>C p.R138T | Missense Mutation (SNP) | VAF 17/614 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV62365134; called by muse, mutect2
- PITRM1 | c.2274C>G p.I758M | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.055); catalogued as COSV99829760; called by muse, mutect2, varscan2
- PLXNB2 | c.5146G>A p.A1716T | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63780810; called by muse, mutect2, varscan2
- RELN | c.3781G>C p.E1261Q | Missense Mutation (SNP) | VAF 117/267 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as COSV58995002; called by muse, mutect2, varscan2
- RNF187 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs1030185199, COSV59959857, COSV59960193; called by muse, mutect2, varscan2
- ROBO3 | c.2695G>A p.A899T | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.877); catalogued as rs771821278; called by muse, mutect2, varscan2
- RYR3 | c.9860C>T p.S3287F (on ENST00000389232; = p.S3288F on NM_001036.6) | Missense Mutation (SNP) | VAF 86/211 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1317783627; called by muse, mutect2, varscan2
- SEPTIN5 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 27/228 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as rs201668611, COSV63530588; called by muse, mutect2, varscan2
- SETMAR | c.1951G>C p.E651Q | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.729); catalogued as COSV100740852; called by muse, mutect2
- SGCZ | c.853G>A p.V285I | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs139184216, COSV101167818; called by muse, mutect2, varscan2
- SLCO4A1 | c.1744G>T p.V582F | Missense Mutation (SNP) | VAF 109/277 reads (39%) | SIFT tolerated (0.67); PolyPhen benign (0.03); catalogued as COSV53889111; called by muse, mutect2, varscan2
- SORCS3 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762674027, COSV63804506; called by muse, mutect2, varscan2
- TAF6L | c.1775C>T p.S592L | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.206); catalogued as rs1319177545, COSV53668464, COSV53670261; called by muse, mutect2, varscan2
- TMEM143 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs867503191; called by muse, mutect2, varscan2
- TMEM79 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 122/345 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as COSV99827851; called by muse, mutect2, varscan2
- TRRAP | c.10057G>C p.E3353Q (on ENST00000359863 / NM_001244580.1; = p.E3324Q on NM_003496.3) | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV62842871; called by muse, mutect2
- UNC80 | c.7456C>T p.R2486W | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs1402034536; called by muse, mutect2, varscan2
- ACSBG1 | c.2146G>A p.D716N | Missense Mutation (SNP) | VAF 98/269 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ADAM23 | c.1337G>C p.R446T | Missense Mutation (SNP) | VAF 40/302 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ANKRD31 | c.3316G>C p.E1106Q | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ARF3 | c.324G>A p.M108I | Missense Mutation (SNP) | VAF 77/169 reads (46%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ARIH1 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- C1orf56 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 90/265 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- CAMK2N1 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 93/229 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CCNL1 | c.1259G>A p.G420E | Missense Mutation (SNP) | VAF 134/273 reads (49%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CRY1 | c.1165G>C p.D389H | Missense Mutation (SNP) | VAF 66/181 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ERBB4 | c.421+2T>C p.X141_splice | Splice Site (SNP) | VAF 26/57 reads (46%) | called by muse, mutect2, varscan2
- ERMP1 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- FAF1 | c.1327C>G p.Q443E | Missense Mutation (SNP) | VAF 62/170 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- FOSB | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- GAREM2 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- GNAQ | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- GTF2A1 | c.700_713del p.Q234Dfs*36 | Frame Shift Del (DEL) | VAF 44/123 reads (36%) | called by mutect2, pindel, varscan2
- HDAC6 | c.776G>A p.G259E | Missense Mutation (SNP) | VAF 71/161 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HIPK3 | c.2123C>T p.S708L | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- IGKV6D-41 | c.184C>G p.Q62E | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.184); called by muse, mutect2
- IL6R | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- KCTD5 | c.476G>C p.R159P | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- LPAR4 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 38/243 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MAP1B | c.7229C>T p.A2410V | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.136); called by muse, mutect2
- MLLT1 | c.1552-1G>A p.X518_splice | Splice Site (SNP) | VAF 90/214 reads (42%) | called by muse, mutect2, varscan2
- MTPAP | c.432C>G p.F144L | Missense Mutation (SNP) | VAF 41/271 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- MYH11 | c.2141G>A p.G714D | Missense Mutation (SNP) | VAF 121/263 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NEDD4L | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 88/258 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2
- NKAP | c.674-1G>A p.X225_splice | Splice Site (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
- NOL12 | c.500C>A p.S167* | Nonsense Mutation (SNP) | VAF 68/181 reads (38%) | called by muse, mutect2, varscan2
- ODF3B | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PCDHGC5 | c.2345C>T p.S782L | Missense Mutation (SNP) | VAF 49/276 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PPFIA3 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 67/170 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, varscan2
- PTPRB | c.4202G>A p.R1401K | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SEC24C | c.322C>T p.Q108* | Nonsense Mutation (SNP) | VAF 75/195 reads (38%) | called by muse, mutect2, varscan2
- SETD2 | c.6596C>T p.S2199F | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- SMYD3 | c.465G>A p.M155I (on ENST00000490107 / NM_001375962.1; = p.M96I on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/192 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SP140 | c.2545G>T p.E849* | Nonsense Mutation (SNP) | VAF 28/221 reads (13%) | called by muse, mutect2, varscan2
- TRPC5 | c.1670G>A p.R557Q | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- XYLB | c.849G>T p.A283= | Splice Region (SNP) | VAF 71/183 reads (39%) | called by muse, mutect2, varscan2
- ZBBX | c.493G>A p.G165R | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZFP69B | c.1374G>C p.Q458H | Missense Mutation (SNP) | VAF 116/259 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- ZNF438 | c.1393_1418del p.G465Tfs*4 | Frame Shift Del (DEL) | VAF 49/180 reads (27%) | called by mutect2, pindel, varscan2
- ZNF467 | c.1693C>T p.H565Y | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ADAMTS3 | c.24G>A p.L8= | Silent (SNP) | VAF 114/297 reads (38%) | called by muse, mutect2, varscan2
- ADAMTS9 | c.3636G>A p.E1212= | Silent (SNP) | VAF 75/157 reads (48%) | called by muse, mutect2, varscan2
- ARHGAP18 | c.72C>T p.V24= | Silent (SNP) | VAF 29/62 reads (47%) | called by muse, mutect2, varscan2
- BCL11A | c.642G>A p.S214= (on ENST00000335712 / NM_001365609.1; = p.S248= on NM_018014.4) | Silent (SNP) | VAF 42/114 reads (37%) | called by muse, mutect2, varscan2
- CACNG7 | c.648C>T p.F216= | Silent (SNP) | VAF 86/255 reads (34%) | catalogued as COSV99711990; called by muse, mutect2, varscan2
- CCM2L | c.411C>T p.I137= | Silent (SNP) | VAF 21/61 reads (34%) | called by muse, mutect2, varscan2
- CCNL2 | c.198G>A p.S66= | Silent (SNP) | VAF 47/263 reads (18%) | catalogued as COSV61224147; called by muse, mutect2, varscan2
- CFAP100 | c.186C>T p.F62= | Silent (SNP) | VAF 88/239 reads (37%) | called by muse, mutect2, varscan2
- CPNE5 | c.1464C>T p.V488= | Silent (SNP) | VAF 11/112 reads (10%) | catalogued as rs749287187; called by muse, mutect2, varscan2
- FBP2 | c.774C>G p.V258= | Silent (SNP) | VAF 23/70 reads (33%) | called by muse, mutect2, varscan2
- FBXL20 | c.15G>A p.V5= | Silent (SNP) | VAF 61/161 reads (38%) | catalogued as COSV52901143; called by muse, mutect2, varscan2
- GANC | c.339A>T p.S113= | Silent (SNP) | VAF 100/237 reads (42%) | called by muse, mutect2, varscan2
- GGA3 | c.684C>T p.L228= (on ENST00000537686 / NM_138619.4; = p.L195= on NM_014001.5) | Silent (SNP) | VAF 73/175 reads (42%) | catalogued as rs1194518137; called by muse, mutect2, varscan2
- GPR141 | c.153C>A p.T51= | Silent (SNP) | VAF 69/156 reads (44%) | called by muse, mutect2, varscan2
- H2BU1 | c.138G>A p.L46= | Silent (SNP) | VAF 71/176 reads (40%) | catalogued as rs1477163629; called by muse, mutect2, varscan2
- HHLA1 | c.660C>A p.G220= | Silent (SNP) | VAF 37/94 reads (39%) | catalogued as rs1327965815; called by muse, mutect2, varscan2
- INPP1 | c.1059C>T p.Y353= | Silent (SNP) | VAF 49/121 reads (40%) | called by muse, mutect2, varscan2
- KLHL31 | c.1389C>T p.V463= | Silent (SNP) | VAF 39/136 reads (29%) | catalogued as rs761430836; called by muse, mutect2, varscan2
- LENG9 | c.303C>T p.F101= | Silent (SNP) | VAF 89/196 reads (45%) | called by muse, mutect2, varscan2
- MPEG1 | c.888C>T p.I296= | Silent (SNP) | VAF 18/60 reads (30%) | called by muse, mutect2
- MYH15 | c.5037G>A p.L1679= | Silent (SNP) | VAF 25/57 reads (44%) | called by muse, mutect2, varscan2
- NGEF | c.1188C>T p.L396= | Silent (SNP) | VAF 69/139 reads (50%) | catalogued as rs759935801; called by muse, mutect2, varscan2
- NUP153 | c.45G>A p.K15= | Silent (SNP) | VAF 45/131 reads (34%) | called by muse, mutect2, varscan2
- PDIA6 | c.682C>T p.L228= | Silent (SNP) | VAF 123/255 reads (48%) | called by muse, mutect2, varscan2
- PHC1 | c.354G>A p.Q118= | Silent (SNP) | VAF 17/151 reads (11%) | called by muse, mutect2, varscan2
- PNPLA3 | c.1023G>A p.K341= | Silent (SNP) | VAF 28/228 reads (12%) | catalogued as rs1309324178; called by muse, mutect2, varscan2
- PPP1CA | c.141G>A p.L47= | Silent (SNP) | VAF 86/221 reads (39%) | called by muse, mutect2, varscan2
- RAB3IL1 | c.729C>T p.F243= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as rs748939226; called by muse, mutect2, varscan2
- RPGRIP1 | c.315G>A p.Q105= | Silent (SNP) | VAF 76/181 reads (42%) | catalogued as COSV52845571; called by muse, mutect2, varscan2
- SEC63 | c.102C>T p.L34= | Silent (SNP) | VAF 44/106 reads (42%) | called by muse, mutect2, varscan2
- SLC15A3 | c.168C>T p.L56= | Silent (SNP) | VAF 18/67 reads (27%) | called by muse, mutect2, varscan2
- SLC25A46 | c.177G>A p.E59= | Silent (SNP) | VAF 72/152 reads (47%) | catalogued as rs777324317; called by muse, mutect2, varscan2
- SLC7A11 | c.1029T>C p.Y343= | Silent (SNP) | VAF 47/108 reads (44%) | catalogued as rs769910192, COSV54929349; called by muse, mutect2, varscan2
- SSU72 | c.126G>A p.V42= | Silent (SNP) | VAF 9/101 reads (9%) | called by muse, mutect2
- STXBP5 | c.459G>A p.Q153= | Silent (SNP) | VAF 8/225 reads (4%) | called by muse, mutect2
- TAF4 | c.672G>A p.A224= | Silent (SNP) | VAF 19/39 reads (49%) | called by muse, varscan2
- TCERG1L | c.1128C>T p.R376= | Silent (SNP) | VAF 21/141 reads (15%) | catalogued as rs761953296, COSV64046353; called by muse, mutect2, varscan2
- TCF12 | c.2028C>T p.T676= | Silent (SNP) | VAF 54/339 reads (16%) | called by muse, mutect2, varscan2
- TIGD5 | c.528G>A p.Q176= | Silent (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2, varscan2
- TMCO6 | c.1191G>A p.V397= | Silent (SNP) | VAF 39/138 reads (28%) | catalogued as rs781733577; called by muse, mutect2, varscan2
- TTLL11 | c.135G>A p.L45= | Silent (SNP) | VAF 42/103 reads (41%) | called by muse, mutect2, varscan2
- VAC14 | c.2013G>A p.L671= | Silent (SNP) | VAF 8/93 reads (9%) | called by muse, mutect2
- ZNF219 | c.735G>A p.Q245= | Silent (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- ACTA2 | c.991-106G>A | Intron (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- ADAM28 | c.-41G>A | 5'UTR (SNP) | VAF 36/122 reads (30%) | catalogued as COSV56099136; called by muse, mutect2, varscan2
- ADORA1 | c.*379G>A | 3'UTR (SNP) | VAF 68/158 reads (43%) | catalogued as rs200687303; called by muse, mutect2
- AFAP1 | c.*3022G>A | 3'UTR (SNP) | VAF 35/92 reads (38%) | called by muse, mutect2, varscan2
- ANKRD44 | c.*256C>T | 3'UTR (SNP) | VAF 31/80 reads (39%) | called by muse, varscan2
- ARHGAP26 | c.*2444T>C | 3'UTR (SNP) | VAF 38/95 reads (40%) | called by muse, mutect2, varscan2
- ATG3 | c.-208G>A | 5'UTR (SNP) | VAF 23/62 reads (37%) | catalogued as rs755971140; called by muse, mutect2, varscan2
- ATM | c.*1227C>T | 3'UTR (SNP) | VAF 37/104 reads (36%) | catalogued as rs187308124; called by muse, mutect2, varscan2
- BCL11B | c.*3669G>T | 3'UTR (SNP) | VAF 37/98 reads (38%) | called by muse, mutect2, varscan2
- BHLHE40 | c.*716G>A | 3'UTR (SNP) | VAF 57/153 reads (37%) | called by muse, mutect2, varscan2
- BMP6 | c.*1369_*1381del | 3'UTR (DEL) | VAF 26/117 reads (22%) | called by pindel, varscan2*
- BTBD7 | c.*2807C>G | 3'UTR (SNP) | VAF 25/71 reads (35%) | called by muse, mutect2, varscan2
- BTLA | c.-79G>A | 5'UTR (SNP) | VAF 10/37 reads (27%) | called by muse, mutect2, varscan2
- C10orf143 | c.69+4120G>A | Intron (SNP) | VAF 65/208 reads (31%) | called by muse, mutect2, varscan2
- C12orf57 | c.229+13C>T | Intron (SNP) | VAF 47/131 reads (36%) | called by muse, mutect2, varscan2
- C14orf132 | chr14:96089097 del T | 3'Flank (DEL) | VAF 58/119 reads (49%) | catalogued as rs575440910; called by mutect2, varscan2
- C19orf38 | c.-65G>C | 5'UTR (SNP) | VAF 81/200 reads (41%) | called by muse, mutect2, varscan2
- CAMK1D | c.*1508G>T | 3'UTR (SNP) | VAF 49/135 reads (36%) | called by muse, mutect2, varscan2
- CAMTA2 | c.-65+496C>T | Intron (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2
- CEP41 | c.*1335A>C | 3'UTR (SNP) | VAF 26/62 reads (42%) | called by muse, mutect2, varscan2
- CITED4 | c.-117G>A | 5'UTR (SNP) | VAF 19/41 reads (46%) | catalogued as rs1161573313; called by muse, mutect2, varscan2
- CLDN4 | chr7:73829342 C>G | 5'Flank (SNP) | VAF 105/294 reads (36%) | called by muse, mutect2, varscan2
- CLVS1 | c.-152+61C>G | Intron (SNP) | VAF 89/230 reads (39%) | called by muse, mutect2, varscan2
- COBL | c.1096+2042G>C | Intron (SNP) | VAF 54/116 reads (47%) | called by muse, mutect2, varscan2
- COLGALT2 | c.-11C>T | 5'UTR (SNP) | VAF 12/37 reads (32%) | called by muse, mutect2, varscan2
- CTTNBP2NL | c.*1835G>A | 3'UTR (SNP) | VAF 70/129 reads (54%) | catalogued as rs561274440; called by muse, mutect2, varscan2
- DCAF6 | chr1:167936657 G>A | 5'Flank (SNP) | VAF 56/152 reads (37%) | called by muse, mutect2, varscan2
- DDX60L | c.*1176G>A | 3'UTR (SNP) | VAF 21/66 reads (32%) | called by muse, mutect2, varscan2
- DENND4B | c.4114+28G>A | Intron (SNP) | VAF 9/161 reads (6%) | called by muse, mutect2
- DMPK | c.433-15C>T | Intron (SNP) | VAF 71/134 reads (53%) | catalogued as rs765503777; called by muse, mutect2, varscan2
- DOCK8 | c.53+399C>T | Intron (SNP) | VAF 5/36 reads (14%) | catalogued as rs771793976; called by muse, mutect2, varscan2
- DPH7 | c.-78C>T | 5'UTR (SNP) | VAF 14/31 reads (45%) | catalogued as rs918388085, COSV99483665; called by muse, mutect2, varscan2
- DSTYK | c.*3111C>T | 3'UTR (SNP) | VAF 14/70 reads (20%) | called by muse, mutect2, varscan2
- DUS3L | c.-1G>A | 5'UTR (SNP) | VAF 18/48 reads (38%) | catalogued as rs1434809865, COSV100288170; called by muse, mutect2, varscan2
- DUSP6 | c.-379G>A | 5'UTR (SNP) | VAF 41/116 reads (35%) | called by muse, mutect2, varscan2
- E2F2 | c.*46C>T | 3'UTR (SNP) | VAF 43/108 reads (40%) | catalogued as COSV100674780; called by muse, mutect2, varscan2
- EDRF1 | c.-41C>T | 5'UTR (SNP) | VAF 64/150 reads (43%) | catalogued as rs1318366440, COSV61762929; called by muse, mutect2, varscan2
- EFNB2 | c.*2274C>A | 3'UTR (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2
- EIF3A | c.-63C>T | 5'UTR (SNP) | VAF 47/106 reads (44%) | called by muse, mutect2, varscan2
- ENPP1 | c.*1592C>T | 3'UTR (SNP) | VAF 28/77 reads (36%) | called by muse, mutect2, varscan2
- EP400 | c.*619G>T | 3'UTR (SNP) | VAF 6/53 reads (11%) | called by muse, mutect2
- EXOC3 | chr5:443104 C>T | 5'Flank (SNP) | VAF 22/43 reads (51%) | called by muse, mutect2, varscan2
- FAM122B | c.-624G>A | 5'UTR (SNP) | VAF 22/56 reads (39%) | called by muse, mutect2, varscan2
- FAM177A1 | c.96+37G>A | Intron (SNP) | VAF 30/100 reads (30%) | called by muse, mutect2, varscan2
- FANCF | chr11:22625960 G>A | 5'Flank (SNP) | VAF 13/90 reads (14%) | called by muse, mutect2
- FGD4 | c.*2270C>T | 3'UTR (SNP) | VAF 38/113 reads (34%) | called by muse, mutect2, varscan2
- FLRT2 | c.*4463C>A | 3'UTR (SNP) | VAF 43/111 reads (39%) | called by muse, mutect2, varscan2
- GAB1 | chr4:143473965 G>A | 3'Flank (SNP) | VAF 38/92 reads (41%) | called by muse, mutect2, varscan2
- GADD45A | c.-234G>A | 5'UTR (SNP) | VAF 20/95 reads (21%) | catalogued as rs1057313722; called by muse, mutect2, varscan2
- GOLT1B | c.117+145G>A | Intron (SNP) | VAF 23/65 reads (35%) | called by muse, mutect2, varscan2
- GPNMB | c.541+609_541+612dup | Intron (INS) | VAF 15/40 reads (38%) | called by mutect2, pindel, varscan2
- GRK4 | c.*40G>A | 3'UTR (SNP) | VAF 130/280 reads (46%) | called by muse, mutect2, varscan2
- GTPBP10 | c.*2546G>C | 3'UTR (SNP) | VAF 14/62 reads (23%) | called by muse, mutect2, varscan2
- HSD17B7P2 | n.821C>G | RNA (SNP) | VAF 61/147 reads (41%) | called by muse, mutect2, varscan2
- IKBKE | c.1836-320C>T | Intron (SNP) | VAF 7/184 reads (4%) | catalogued as rs782121021; called by muse, mutect2
- IL6R | chr1:154470231 G>A | 3'Flank (SNP) | VAF 53/152 reads (35%) | called by muse, mutect2, varscan2
- IQGAP1 | c.-72G>C | 5'UTR (SNP) | VAF 10/190 reads (5%) | called by muse, mutect2
- ISCU | c.419-495G>A | Intron (SNP) | VAF 26/65 reads (40%) | catalogued as rs893349302; called by muse, mutect2, varscan2
- ITGAX | c.*746G>A | 3'UTR (SNP) | VAF 20/87 reads (23%) | catalogued as rs1164350566; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1183+86G>A | Intron (SNP) | VAF 56/128 reads (44%) | called by muse, mutect2
- KCNA5 | c.*793G>T | 3'UTR (SNP) | VAF 14/45 reads (31%) | called by muse, mutect2, varscan2
- KCNAB2 | c.*1857T>G | 3'UTR (SNP) | VAF 59/138 reads (43%) | called by muse, mutect2, varscan2
- KCND1 | c.*773G>A | 3'UTR (SNP) | VAF 5/140 reads (4%) | called by muse, mutect2
- KCNS1 | c.*2044A>T | 3'UTR (SNP) | VAF 7/135 reads (5%) | called by muse, mutect2
- KITLG | c.-177C>G | 5'UTR (SNP) | VAF 38/83 reads (46%) | catalogued as rs1400174221, COSV99933186; called by muse, mutect2, varscan2
- KLF11 | c.42+114C>T | Intron (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- KLK2 | c.630+71G>A | Intron (SNP) | VAF 112/262 reads (43%) | called by muse, mutect2, varscan2
- LAMP3 | c.*534C>T | 3'UTR (SNP) | VAF 11/22 reads (50%) | catalogued as rs1396108275; called by muse, mutect2, varscan2
- LDHAL6A | c.418+3334G>A | Intron (SNP) | VAF 35/284 reads (12%) | called by muse, mutect2, varscan2
- LEF1 | c.-221G>A | 5'UTR (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- LIN28B | c.*621T>C | 3'UTR (SNP) | VAF 27/63 reads (43%) | catalogued as rs1176153371, COSV100559153, COSV61493531; called by muse, mutect2, varscan2
- LMAN1 | c.*3164C>T | 3'UTR (SNP) | VAF 38/93 reads (41%) | catalogued as rs1364541803; called by muse, mutect2, varscan2
- LMAN1 | c.*2474G>A | 3'UTR (SNP) | VAF 39/97 reads (40%) | called by muse, mutect2, varscan2
- LRRC19 | c.*1200C>T | 3'UTR (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
- MACROD2 | chr20:16052397 C>T | 3'Flank (SNP) | VAF 20/61 reads (33%) | called by muse, mutect2, varscan2
- MARCHF6 | c.*1598A>G | 3'UTR (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2, varscan2
- MFHAS1 | c.*1736_*1755delinsCATGTGTGTAAAAC | 3'UTR (DEL) | VAF 4/32 reads (13%) | called by pindel, varscan2*
- MOB4 | chr2:197515605 G>A | 5'Flank (SNP) | VAF 12/35 reads (34%) | called by muse, mutect2, varscan2
- MRPS27 | c.*1173G>C | 3'UTR (SNP) | VAF 62/169 reads (37%) | called by muse, mutect2, varscan2
- MUC19 | n.20574C>T | RNA (SNP) | VAF 45/116 reads (39%) | called by muse, mutect2, varscan2
- NAPRT | c.355-17G>A | Intron (SNP) | VAF 37/82 reads (45%) | called by muse, mutect2, varscan2
- NCOA7 | c.2245-1678C>T | Intron (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
- NUCKS1 | c.*4155del | 3'UTR (DEL) | VAF 49/153 reads (32%) | called by mutect2, pindel, varscan2
- PARD3 | c.*464C>T | 3'UTR (SNP) | VAF 60/169 reads (36%) | called by muse, mutect2, varscan2
- PDAP1 | c.*1992G>A | 3'UTR (SNP) | VAF 8/53 reads (15%) | called by muse, varscan2
- PDP1 | c.-45+866_-45+901del | Intron (DEL) | VAF 54/151 reads (36%) | called by mutect2, pindel
- PEX5 | chr12:7210894 G>T | 3'Flank (SNP) | VAF 48/148 reads (32%) | called by muse, mutect2, varscan2
- PHF20L1 | c.1184-84C>T | Intron (SNP) | VAF 13/28 reads (46%) | called by muse, mutect2
- PLCXD3 | c.*267A>G | 3'UTR (SNP) | VAF 28/76 reads (37%) | called by muse, mutect2, varscan2
- PMFBP1 | c.165+308G>A | Intron (SNP) | VAF 5/97 reads (5%) | called by muse, mutect2
- POLR2M | c.113+178C>G | Intron (SNP) | VAF 40/102 reads (39%) | called by muse, mutect2, varscan2
- PRELID3B | c.*555C>T | 3'UTR (SNP) | VAF 54/134 reads (40%) | called by muse, mutect2, varscan2
- PRSS37 | c.-273G>C | 5'UTR (SNP) | VAF 37/118 reads (31%) | called by muse, mutect2, varscan2
- RAP2A | c.*358C>G | 3'UTR (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
- RAPGEF1 | chr9:131739816 G>A | 5'Flank (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2
- RCC1 | c.-153+23C>T | Intron (SNP) | VAF 35/96 reads (36%) | called by muse, mutect2, varscan2
- RCE1 | c.185+58G>A | Intron (SNP) | VAF 51/147 reads (35%) | called by muse, mutect2, varscan2
- RMND5A | c.-320C>T | 5'UTR (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2, varscan2
- RORA | c.*5751G>A | 3'UTR (SNP) | VAF 50/109 reads (46%) | called by muse, mutect2, varscan2
- RRM2B | c.48+51T>C | Intron (SNP) | VAF 129/293 reads (44%) | called by muse, mutect2, varscan2
- S1PR3 | c.-260G>A | 5'UTR (SNP) | VAF 46/112 reads (41%) | called by muse, mutect2, varscan2
- SAXO2 | c.-20G>A | 5'UTR (SNP) | VAF 46/132 reads (35%) | called by muse, mutect2, varscan2
- SHISA9 | c.564-5246C>T | Intron (SNP) | VAF 16/127 reads (13%) | called by muse, mutect2, varscan2
- SHROOM1 | c.-115C>T | 5'UTR (SNP) | VAF 6/144 reads (4%) | called by muse, mutect2
- SLC16A10 | c.-6C>T | 5'UTR (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
- SLC25A4 | c.-48G>T | 5'UTR (SNP) | VAF 30/79 reads (38%) | called by muse, mutect2, varscan2
- SNAPC1 | c.*967_*968insA | 3'UTR (INS) | VAF 9/40 reads (23%) | called by pindel, varscan2
- SNORD115-26 | n.12G>A | RNA (SNP) | VAF 41/104 reads (39%) | catalogued as rs947785492; called by muse, mutect2, varscan2
- SOX6 | chr11:15972657 A>C | 3'Flank (SNP) | VAF 47/109 reads (43%) | called by muse, mutect2, varscan2
- SPEF2 | c.1524+335A>C | Intron (SNP) | VAF 29/53 reads (55%) | called by muse, mutect2, varscan2
- ST20-MTHFS | c.-12+65C>T | Intron (SNP) | VAF 29/83 reads (35%) | called by muse, mutect2, varscan2
- ST8SIA4 | c.-318G>A | 5'UTR (SNP) | VAF 29/90 reads (32%) | called by muse, mutect2, varscan2
- SYNRG | c.-13G>A | 5'UTR (SNP) | VAF 50/133 reads (38%) | called by muse, mutect2, varscan2
- SYT4 | c.*72A>G | 3'UTR (SNP) | VAF 45/98 reads (46%) | called by muse, mutect2, varscan2
- TBC1D31 | c.77+513C>A | Intron (SNP) | VAF 23/212 reads (11%) | called by muse, mutect2, varscan2
- TCAF1P1 | n.255G>A | RNA (SNP) | VAF 51/201 reads (25%) | called by muse, mutect2, varscan2
- TCF7 | c.*1181G>A | 3'UTR (SNP) | VAF 5/29 reads (17%) | catalogued as rs1160023271; called by muse, mutect2
- TECRL | c.*789G>C | 3'UTR (SNP) | VAF 18/48 reads (38%) | called by muse, mutect2
- TEX21P | n.1623G>A | RNA (SNP) | VAF 87/267 reads (33%) | catalogued as rs1211250313; called by muse, mutect2, varscan2
- TIAM1 | chr21:31559281 C>T | 5'Flank (SNP) | VAF 18/126 reads (14%) | catalogued as rs1049829777; called by muse, mutect2, varscan2
- TMA7 | c.160+38G>A | Intron (SNP) | VAF 12/19 reads (63%) | catalogued as rs759347675; called by muse, varscan2
- TMEM154 | c.*1627C>G | 3'UTR (SNP) | VAF 28/87 reads (32%) | called by muse, mutect2
- TMEM182 | c.*1222C>T | 3'UTR (SNP) | VAF 4/99 reads (4%) | called by muse, mutect2
- TMEM45B | c.*300G>A | 3'UTR (SNP) | VAF 16/42 reads (38%) | called by muse, mutect2, varscan2
- TOP1 | c.975+34C>T | Intron (SNP) | VAF 10/171 reads (6%) | called by muse, mutect2
- TXNDC5 | c.*522G>A | 3'UTR (SNP) | VAF 41/125 reads (33%) | called by muse, mutect2, varscan2
- UBE2J1 | c.-113G>A | 5'UTR (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2
- UPRT | c.*925A>C | 3'UTR (SNP) | VAF 36/91 reads (40%) | called by muse, mutect2
- UXS1 | c.-34G>C | 5'UTR (SNP) | VAF 46/102 reads (45%) | called by muse, mutect2, varscan2
- VPS13A | c.*4738_*4771del | 3'UTR (DEL) | VAF 20/74 reads (27%) | called by mutect2, pindel
- XAF1 | c.-27C>T | 5'UTR (SNP) | VAF 4/84 reads (5%) | called by muse, mutect2
- YY1 | c.*1603C>T | 3'UTR (SNP) | VAF 17/115 reads (15%) | called by muse, mutect2, varscan2
- ZCCHC14 | c.*3013G>A | 3'UTR (SNP) | VAF 39/96 reads (41%) | called by muse, mutect2
- ZNF572 | c.*323G>A | 3'UTR (SNP) | VAF 27/63 reads (43%) | called by muse, mutect2, varscan2
